TCGA case TCGA-EA-A556 — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Cervix uteri; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2d34e9a3-298c-4365-b7a1-a507c7f069cd

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 38 years; Vital status: Alive.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 38.3 years (13,988 days); Year of diagnosis: 2012; Method of diagnosis: Cytology; AJCC pathologic T: T1b1; AJCC pathologic N: N0; AJCC pathologic M: M0; FIGO stage: Stage IB1; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 7.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Day -1 (preoperative): ECOG performance status: 1.
- Days to follow up: 0 days; Disease response: Tumor Free.
- Days to follow up: 453 days (1.2 years); Disease response: Tumor Free; ECOG performance status: 0.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Live Birth.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal; Pregnant at diagnosis: No.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Miscarriage.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Induced Abortion.
- Timepoint category: Initial Diagnosis; Weight: 62 kg; Height: 160 cm; BMI: 24.2.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used; Hysterectomy type: Radical Hysterectomy.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 20; Age at onset: 18.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EA-A556-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 360 mg.
  Slide TCGA-EA-A556-01A-01-TSA: Section location: Top; Percent tumor cells: 97; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EA-A556-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EA-A556-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 1; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Total pregnancy count: 1; Tobacco smoking history indicator: 2; Submitted tumor site: Cervical; Histologic diagnosis: Endometrioid Adenocarcinoma of Endocervix; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid); Lymph nodes examined: Yes; Corpus involvement: Absent; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Performance status other timing: At time of last contact; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 453 days; disease-specific survival: no event (censored), 453 days; disease-free interval: no event (censored), 453 days; progression-free interval: no event (censored), 453 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EA-A556-01A-11D-A26F-01): tumor purity 0.7, ploidy 3.96, whole-genome doublings 1.
